Somatic mutation profile of tumor specimen 0DTFRO from CCDI case PBCFWI, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Adrenal cortical carcinoma; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 3.1 years (1,119 days).
Specimen 0DTFRO: Tissue type: Tumor; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2922e5b4-88b3-4831-85a1-b0ed6303b347.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DTFRU (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e6cf9ad3-b7c6-4255-a2dd-3953ce6a2fcd

The open-access MAF lists 50 somatic variants for this specimen: 30 protein-altering or splice-affecting, 11 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 26, Silent 11, Intron 6, Splice Region 2, Splice Site 1, 3'UTR 1, RNA 1, Nonsense Mutation 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.638G>A p.R213Q | Missense Mutation (SNP) | VAF 414/678 reads (61%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs587778720, CM004906, CM022474, COSV52665093, COSV52668963, COSV52693072; ClinVar: drug response / pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ARHGAP23 | c.895C>T p.R299W | Missense Mutation (SNP) | VAF 23/217 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as rs775996184; called by muse, mutect2, varscan2
- CACNA1H | c.2932G>C p.V978L | Missense Mutation (SNP) | VAF 110/818 reads (13%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.984); catalogued as COSV61993677; called by muse, mutect2, varscan2
- CARD16 | c.240C>G p.D80E | Missense Mutation (SNP) | VAF 139/923 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1206682409; called by muse, mutect2, varscan2
- DNAJC25 | c.680A>C p.K227T | Missense Mutation (SNP) | VAF 56/1601 reads (3%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as COSV57958028; called by muse, mutect2
- FIG4 | c.2714G>A p.R905H | Missense Mutation (SNP) | VAF 114/1458 reads (8%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.893); catalogued as rs780921285, COSV100019281; called by muse, mutect2
- KHDC3L | c.23C>T p.P8L | Missense Mutation (SNP) | VAF 253/1536 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.488); catalogued as rs757863032, COSV100951072; called by muse, mutect2, varscan2
- MESD | c.584G>A p.G195E | Missense Mutation (SNP) | VAF 173/1138 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.082); catalogued as rs775699712; called by muse, mutect2, varscan2
- PLPBP | c.562C>T p.H188Y | Missense Mutation (SNP) | VAF 128/1272 reads (10%) | SIFT tolerated (0.7); PolyPhen benign (0.006); catalogued as rs774906659, COSV100065796; called by muse, mutect2
- USP13 | c.866C>T p.A289V | Missense Mutation (SNP) | VAF 330/983 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.125); catalogued as rs200404045; called by muse, mutect2, varscan2
- ABCA5 | c.731A>C p.K244T | Missense Mutation (SNP) | VAF 32/569 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- AFDN | c.2834T>A p.V945D | Missense Mutation (SNP) | VAF 83/1989 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- ALOX12B | c.1877G>T p.C626F | Missense Mutation (SNP) | VAF 159/926 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); called by muse, mutect2, varscan2
- CCDC141 | c.701T>C p.L234P | Missense Mutation (SNP) | VAF 72/960 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- COBL | c.1149G>T p.Q383H | Missense Mutation (SNP) | VAF 145/2202 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.339); called by muse, mutect2
- CUX2 | c.225G>C p.V75= | Splice Region (SNP) | VAF 44/976 reads (5%) | called by muse, mutect2
- DZIP3 | c.919-1G>C p.X307_splice | Splice Site (SNP) | VAF 53/550 reads (10%) | called by muse, mutect2, varscan2
- HK3 | c.1205C>T p.A402V | Missense Mutation (SNP) | VAF 153/1431 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- LMO7DN | n.282C>G | Splice Region (SNP) | VAF 18/574 reads (3%) | called by muse, mutect2
- LTB | c.127G>T p.V43L | Missense Mutation (SNP) | VAF 68/1532 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.211); called by muse, mutect2
- MYO5A | c.1759A>C p.M587L | Missense Mutation (SNP) | VAF 107/815 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- NOTCH1 | c.5510A>T p.Q1837L | Missense Mutation (SNP) | VAF 173/1327 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.218); called by muse, mutect2, varscan2
- PCDHB9 | c.971G>C p.G324A | Missense Mutation (SNP) | VAF 70/972 reads (7%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.139); called by muse, mutect2
- PCNT | c.6577C>A p.P2193T | Missense Mutation (SNP) | VAF 32/318 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.023); called by muse, mutect2
- PIWIL3 | c.1084A>G p.R362G | Missense Mutation (SNP) | VAF 85/712 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); called by muse, mutect2, varscan2
- PLPPR3 | c.1685C>G p.A562G (on ENST00000520876 / NM_001270366.2; = p.A590G on NM_024888.2) | Missense Mutation (SNP) | VAF 65/519 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- PTPRB | c.1032C>A p.H344Q | Missense Mutation (SNP) | VAF 67/1338 reads (5%) | SIFT tolerated (0.32); PolyPhen benign (0.003); called by muse, mutect2
- REXO1 | c.3121C>T p.L1041F | Missense Mutation (SNP) | VAF 222/2482 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.564); called by muse, mutect2
- SYNGR2 | c.265G>C p.D89H | Missense Mutation (SNP) | VAF 57/844 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TSPAN10 | c.249C>A p.C83* (on ENST00000574882 / NM_001290212.1; = p.C45* on NM_031945.4) | Nonsense Mutation (SNP) | VAF 83/403 reads (21%) | called by muse, mutect2, varscan2
- CCPG1 | c.1227T>C p.H409= | Silent (SNP) | VAF 54/636 reads (8%) | called by muse, mutect2
- CEACAM5 | c.1695C>T p.D565= | Silent (SNP) | VAF 62/1359 reads (5%) | catalogued as rs782644830, COSV55751523; called by muse, mutect2
- GPANK1 | c.129C>T p.F43= | Silent (SNP) | VAF 184/1430 reads (13%) | catalogued as rs201844667; called by muse, mutect2, varscan2
- HUWE1 | c.4185A>T p.S1395= | Silent (SNP) | VAF 109/428 reads (25%) | called by muse, mutect2, varscan2
- MAP3K12 | c.283C>T p.L95= | Silent (SNP) | VAF 121/1155 reads (10%) | catalogued as COSV57236466; called by muse, mutect2, varscan2
- MEGF6 | c.3567G>A p.G1189= | Silent (SNP) | VAF 107/812 reads (13%) | called by muse, mutect2, varscan2
- OTOF | c.3174G>A p.K1058= (on ENST00000272371 / NM_194248.3; = p.K311= on NM_004802.4) | Silent (SNP) | VAF 95/1210 reads (8%) | catalogued as rs199931485; called by muse, mutect2
- PRKX | c.198G>T p.V66= | Silent (SNP) | VAF 42/1006 reads (4%) | called by muse, mutect2
- SYMPK | c.435A>G p.V145= | Silent (SNP) | VAF 84/838 reads (10%) | called by muse, mutect2
- TNKS | c.144C>G p.P48= | Silent (SNP) | VAF 96/481 reads (20%) | called by muse, mutect2, varscan2
- TONSL | c.4077G>C p.R1359= | Silent (SNP) | VAF 39/715 reads (5%) | called by muse, mutect2
- ADAM15 | c.744+28C>G | Intron (SNP) | VAF 78/880 reads (9%) | called by muse, mutect2
- ADCY4 | c.2428-90T>A | Intron (SNP) | VAF 8/130 reads (6%) | called by muse, mutect2
- IQSEC2 | c.737+12235G>T | Intron (SNP) | VAF 44/562 reads (8%) | called by muse, mutect2
- PIP5K1C | c.-17G>A | 5'UTR (SNP) | VAF 24/172 reads (14%) | called by muse, mutect2, varscan2
- PREPL | c.2094+40C>G | Intron (SNP) | VAF 100/492 reads (20%) | called by muse, mutect2
- SLC2A3 | c.674-21C>T | Intron (SNP) | VAF 136/2116 reads (6%) | called by muse, mutect2
- TCP10L3 | n.1955G>A | RNA (SNP) | VAF 141/1088 reads (13%) | catalogued as rs569585072; called by muse, mutect2, varscan2
- USP21 | c.1384+73G>A | Intron (SNP) | VAF 46/479 reads (10%) | called by muse, mutect2
- ZSCAN9 | c.*53G>C | 3'UTR (SNP) | VAF 26/197 reads (13%) | called by muse, mutect2, varscan2
